Somatic mutation profile of tumor specimen SM-JU342 (aliquot 7316UP-219) from CPTAC case C243909, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen SM-JU342: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f09fcfe-f2e8-477d-85da-d1b3044e535e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105279 (Blood Derived Normal), aliquot 7316UP-219-1105279; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af1ea87a-b37d-407a-91b7-3d8fe5eb6d47

The open-access MAF lists 909 somatic variants for this specimen: 601 protein-altering or splice-affecting, 203 silent, 105 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 500, Silent 203, Intron 52, Nonsense Mutation 51, RNA 21, Frame Shift Del 16, 5'UTR 14, Splice Site 13, Splice Region 10, 3'UTR 10, Frame Shift Ins 6, 5'Flank 5.

Variants (750 of 909; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 49/90 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs863225060, COSV55878075, COSV55925758; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 127/209 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs762543032, CM100393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.403T>G p.C135G | Missense Mutation (SNP) | VAF 274/302 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A1CF | c.1096G>T p.G366* | Nonsense Mutation (SNP) | VAF 106/289 reads (37%) | catalogued as COSV50958623; called by muse, mutect2, varscan2
- ACHE | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs1262901790, COSV53820206; called by muse, mutect2
- ADAM20 | c.1155G>A p.W385* | Nonsense Mutation (SNP) | VAF 22/268 reads (8%) | catalogued as rs1352435072; called by muse, mutect2
- ADAMTS2 | c.2486C>G p.S829* | Nonsense Mutation (SNP) | VAF 57/261 reads (22%) | catalogued as COSV52370863, COSV52383930; called by muse, mutect2, varscan2
- AFM | c.957A>T p.K319N | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.038); catalogued as COSV56922667; called by muse, mutect2, varscan2
- AGTPBP1 | c.1369G>A p.V457I (on ENST00000357081 / NM_001330701.2; = p.V417I on NM_015239.2) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs745710606; called by muse, mutect2, varscan2
- ANK3 | c.12236G>A p.R4079K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV99781711; called by muse, varscan2
- ANO7 | c.962C>A p.A321E (on ENST00000274979; = p.A267E on NM_001370694.2) | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375507696; called by muse, mutect2, varscan2
- ANXA13 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 292/410 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1409407846; called by muse, mutect2, varscan2
- APCS | c.468G>T p.Q156H | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54818113; called by muse, mutect2
- APOB | c.2329C>A p.L777I | Missense Mutation (SNP) | VAF 180/270 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99267907; called by muse, mutect2, varscan2
- ARAP3 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1186879516; called by muse, mutect2, varscan2
- ARFGAP3 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 137/298 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV54311444; called by muse, mutect2, varscan2
- ARHGAP12 | c.1900C>T p.L634F | Missense Mutation (SNP) | VAF 109/301 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60961844, COSV60963784; called by muse, mutect2, varscan2
- ARHGAP22 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 60/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201381170; called by muse, mutect2, varscan2
- ARHGAP9 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 56/872 reads (6%) | catalogued as rs760103624, COSV57364355; called by muse, mutect2
- ASTN1 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56072577; called by muse, mutect2, varscan2
- BRWD3 | c.3224C>A p.P1075Q | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs1051653380; called by muse, mutect2, varscan2
- C20orf144 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 243/554 reads (44%) | catalogued as rs1183825290; called by muse, mutect2, varscan2
- C9 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 38/595 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1460235579; called by muse, mutect2
- C9orf131 | c.1454T>C p.M485T | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1380081534; called by muse, mutect2, varscan2
- CA12 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 73/444 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs931534148; called by muse, mutect2, varscan2
- CACNA1G | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 91/256 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as rs766099998; called by muse, mutect2, varscan2
- CACNA2D2 | c.2869C>T p.R957W (on ENST00000479441 / NM_001174051.3; = p.R950W on NM_006030.4) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1209696501, COSV99817832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN15 | c.2941G>T p.G981C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54836374, COSV99562579; called by muse, mutect2, varscan2
- CCHCR1 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 42/489 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.351); catalogued as COSV66184418; called by muse, mutect2
- CD163 | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747001854; called by muse, mutect2, varscan2
- CDC40 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs890438403; called by muse, mutect2, varscan2
- CDH9 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV50300303; called by muse, mutect2, varscan2
- CDK1 | c.107G>T p.R36I | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100358872; called by muse, mutect2, varscan2
- CDX4 | c.461A>T p.H154L | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV100999147; called by muse, mutect2, varscan2
- CEP85 | c.727A>G p.N243D | Missense Mutation (SNP) | VAF 79/137 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs150424067; called by muse, mutect2, varscan2
- CFAP47 | c.1174A>C p.S392R | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.594); catalogued as COSV52886455, COSV52894132; called by muse, mutect2, varscan2
- CHAF1A | c.1671G>A p.M557I | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as rs764009577; called by muse, mutect2, varscan2
- COL22A1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 98/150 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV57364241; called by muse, mutect2, varscan2
- COL6A3 | c.4108G>A p.A1370T | Missense Mutation (SNP) | VAF 101/928 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as rs372234605, COSV55085755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPLANE1 | c.7838C>G p.S2613* | Nonsense Mutation (SNP) | VAF 36/452 reads (8%) | catalogued as COSV99949726; called by muse, mutect2
- CRACD | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs776352029; called by muse, mutect2, varscan2
- CSMD1 | c.9653C>A p.P3218Q (on ENST00000520002; = p.P3217Q on NM_033225.6) | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV59306150; called by muse, mutect2, varscan2
- CSMD1 | c.3701G>T p.G1234V (on ENST00000520002; = p.G1233V on NM_033225.6) | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs763737608; called by muse, mutect2, varscan2
- CSMD3 | c.9299G>T p.G3100V (on ENST00000297405 / NM_001363185.1; = p.G2931V on NM_052900.3) | Missense Mutation (SNP) | VAF 383/691 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52184151; called by muse, mutect2, varscan2
- CSMD3 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 436/554 reads (79%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.023); catalogued as COSV52092277, COSV52126694; called by muse, mutect2, varscan2
- DAAM1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 49/387 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62834150; called by muse, mutect2, varscan2
- DAGLB | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs755797799; called by muse, mutect2, varscan2
- DCDC1 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as rs566810543; called by muse, mutect2, varscan2
- DES | c.1147C>A p.R383S | Missense Mutation (SNP) | VAF 252/530 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64660959; called by muse, mutect2
- DGKQ | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.873); catalogued as COSV99298305; called by muse, mutect2, varscan2
- DMD | c.2821C>T p.P941S | Missense Mutation (SNP) | VAF 162/415 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs1477425663; called by muse, mutect2, varscan2
- DNAH8 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV59451127; called by muse, mutect2
- DST | c.2437G>A p.D813N (on ENST00000361203 / NM_001374722.1; = p.D487N on NM_001723.6) | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs367639314; called by muse, mutect2, varscan2
- DYNC1H1 | c.13349C>T p.T4450M | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as rs146087540; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I1 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100268810, COSV61468022; called by muse, mutect2, varscan2
- ENAH | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV52869089; called by muse, mutect2
- EOMES | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs536220570; called by muse, mutect2, varscan2
- EPHA4 | c.2197G>T p.G733W | Missense Mutation (SNP) | VAF 228/551 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56037210; called by muse, mutect2, varscan2
- ERGIC2 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs774859065; called by muse, mutect2, varscan2
- ETS2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV62872572; called by muse, mutect2, varscan2
- EYS | c.3684G>A p.M1228I | Missense Mutation (SNP) | VAF 209/444 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58203363; called by muse, mutect2, varscan2
- F7 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs147680958, CM001151; called by muse, mutect2, varscan2
- FAM184B | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 45/82 reads (55%) | catalogued as rs1188972903, COSV53957258; called by muse, mutect2, varscan2
- FARP2 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs777762724; called by muse, mutect2, varscan2
- FGA | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 115/236 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs746087673, CD035514, COSV57393503, COSV57402272; called by muse, mutect2, varscan2
- FLII | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58943841; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV100438086; called by muse, mutect2, varscan2
- FRY | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 61/310 reads (20%) | catalogued as rs776773297, COSV66567927; called by muse, mutect2, varscan2
- FSIP2 | c.15454G>A p.E5152K | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1197100532; called by muse, mutect2, varscan2
- GABPA | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV61396593; called by muse, mutect2, varscan2
- GABRA5 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV59479388; called by muse, varscan2
- GAL3ST3 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757211741, COSV100360733; called by muse, mutect2
- GGPS1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 50/88 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV51396852; called by muse, mutect2, varscan2
- GP2 | c.766C>A p.L256M (on ENST00000381362 / NM_001007240.3; = p.L253M on NM_001502.4) | Missense Mutation (SNP) | VAF 60/417 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390353891, COSV56894286; called by muse, mutect2, varscan2
- GPM6A | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs1345183983; called by muse, mutect2, varscan2
- GPRASP1 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | catalogued as rs1294027624, COSV100851087; called by muse, mutect2, varscan2
- GRM8 | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100283592; called by muse, mutect2, varscan2
- H2BW1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs1264516494; called by muse, mutect2, varscan2
- HCST | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 154/172 reads (90%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.072); catalogued as rs777647806; called by muse, mutect2, varscan2
- HDAC9 | c.2035C>A p.R679= | Splice Region (SNP) | VAF 117/140 reads (84%) | catalogued as COSV67786067; called by muse, mutect2, varscan2
- HERC2 | c.7361C>T p.S2454L | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs879255382, COSV55350151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HS3ST6 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs567994936; called by muse, mutect2, varscan2
- IL11RA | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 163/366 reads (45%) | catalogued as rs775348905; called by muse, mutect2, varscan2
- IL27RA | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs994827825, COSV54599596; called by muse, mutect2, varscan2
- INSYN2B | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV99911494; called by muse, mutect2, varscan2
- IPP | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs780057516; called by muse, mutect2, varscan2
- IQSEC2 | c.3076C>T p.P1026S (on ENST00000642864 / NM_001111125.3; = p.P821S on NM_015075.2) | Missense Mutation (SNP) | VAF 59/498 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.084); catalogued as COSV64728417; called by muse, mutect2, varscan2
- ITGBL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV66009702; called by muse, mutect2, varscan2
- IVL | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 36/472 reads (8%) | catalogued as COSV64217090; called by muse, mutect2
- KALRN | c.3252C>A p.N1084K | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53785502; called by muse, mutect2, varscan2
- KCNQ3 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 64/588 reads (11%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.548); catalogued as rs1172699877; called by muse, mutect2, varscan2
- KEAP1 | c.830C>A p.T277K | Missense Mutation (SNP) | VAF 254/317 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV50262958; called by muse, mutect2, varscan2
- KLHL29 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs771088004; called by muse, mutect2, varscan2
- KMT2C | c.4889C>A p.S1630* | Nonsense Mutation (SNP) | VAF 36/566 reads (6%) | catalogued as COSV51501941; called by muse, mutect2
- KRT84 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 524/737 reads (71%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1475558984; called by muse, mutect2, varscan2
- LAMA5 | c.4299C>G p.N1433K | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs576766054, COSV99439506; called by muse, mutect2, varscan2
- LCE1B | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.923); catalogued as COSV63980046; called by muse, mutect2
- LRCH1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 74/123 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1209521446, COSV60844120; called by muse, mutect2, varscan2
- LRRC7 | c.3160C>A p.P1054T (on ENST00000651989 / NM_001370785.2; = p.P1021T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1428457255, COSV50608408; called by muse, mutect2, varscan2
- LRRFIP1 | c.1147G>A p.E383K (on ENST00000392000 / NM_001137552.2; = p.E359K on NM_004735.4) | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as rs147303790; called by muse, mutect2
- MALRD1 | c.6098G>T p.G2033V | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1423736208; called by muse, mutect2, varscan2
- MARCKS | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 264/438 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100893018; called by muse, mutect2, varscan2
- MAT2B | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as COSV55201041; called by muse, mutect2, varscan2
- MC3R | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV54763127; called by muse, mutect2, varscan2
- MGAT2 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1476271337, COSV53567037; called by muse, mutect2
- MIPOL1 | c.606G>C p.M202I | Missense Mutation (SNP) | VAF 134/232 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV59390976; called by muse, mutect2, varscan2
- MMP2 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 154/389 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161173; called by muse, mutect2, varscan2
- MPP7 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 182/363 reads (50%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.55); catalogued as rs762252605, COSV61739431; called by muse, mutect2, varscan2
- MTUS2 | c.1358T>C p.I453T | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1003183536; called by muse, mutect2, varscan2
- MUC17 | c.9346C>A p.P3116T | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.341); catalogued as rs562321094; called by muse, mutect2, varscan2
- MUC22 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious, low confidence (0.01); catalogued as rs1225649659, COSV73736210; called by muse, mutect2
- N6AMT1 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs757481872; called by muse, mutect2, varscan2
- NAALAD2 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58964563; called by muse, mutect2, varscan2
- NBEA | c.4375G>C p.E1459Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59765586; called by muse, mutect2, varscan2
- NEFL | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 73/409 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1563251398, COSV99648163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHSL2 | c.1702G>C p.D568H (on ENST00000510661; = p.D934H on NM_001013627.2) | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as rs1237800923, COSV101029883; called by muse, mutect2, varscan2
- NLRP1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 698/838 reads (83%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs145709003; called by mutect2, varscan2
- NLRP5 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs372305298, COSV66768008; called by muse, mutect2, varscan2
- NOP58 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV51895561; called by muse, varscan2
- NPBWR2 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.14); catalogued as COSV63900403; called by muse, mutect2, varscan2
- NPY1R | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 112/336 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV56714298, COSV56715481; called by muse, mutect2, varscan2
- NRBP1 | c.1268C>G p.P423R | Missense Mutation (SNP) | VAF 257/401 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV51993925; called by muse, mutect2, varscan2
- NRK | c.398C>G p.A133G | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.514); catalogued as COSV54590582; called by muse, mutect2, varscan2
- NTRK1 | c.354T>A p.S118R | Missense Mutation (SNP) | VAF 143/808 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as CD087748; called by muse, mutect2, varscan2
- OLFM4 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99524180; called by muse, mutect2, varscan2
- OLFML2A | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 120/205 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202197796; called by muse, mutect2, varscan2
- OR14A16 | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 113/193 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1374004830; called by muse, mutect2, varscan2
- OR2T33 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 249/432 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58815134; called by muse, mutect2, varscan2
- OR4A16 | c.855C>A p.Y285* | Nonsense Mutation (SNP) | VAF 73/85 reads (86%) | catalogued as COSV59045243, COSV59045505; called by muse, mutect2, varscan2
- OR51B2 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 101/115 reads (88%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs758948105; called by muse, mutect2, varscan2
- OR5AR1 | c.704T>A p.L235H | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.037); catalogued as COSV100265624, COSV100265857; called by muse, mutect2, varscan2
- P3H1 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs200935208; called by muse, mutect2, varscan2
- PASD1 | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.224); catalogued as rs773014348; called by muse, mutect2, varscan2
- PCDH19 | c.644A>C p.D215A | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as rs935781189; called by muse, mutect2, varscan2
- PCDHB13 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 147/290 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53393831; called by muse, mutect2, varscan2
- PCDHGB1 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs551145874, COSV53913385; called by muse, mutect2
- PCDHGB5 | c.2397+4A>T | Splice Region (SNP) | VAF 20/92 reads (22%) | catalogued as rs764084750; called by muse, mutect2
- PCNX2 | c.4249G>A p.D1417N | Missense Mutation (SNP) | VAF 60/540 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237031185, COSV99265907; called by muse, mutect2, varscan2
- PDZD2 | c.2693C>T p.S898L | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs761729480; called by muse, mutect2, varscan2
- PGAP6 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51739093; called by muse, mutect2, varscan2
- PGK2 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 124/312 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59165222; called by muse, mutect2, varscan2
- PIN4 | c.353C>A p.P118Q (on ENST00000664196; = p.P93Q on NM_006223.4) | Missense Mutation (SNP) | VAF 104/204 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1423088655, COSV54485019; called by muse, mutect2, varscan2
- PLCE1 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs754933489, COSV53357882; called by muse, mutect2, varscan2
- POTEA | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 125/312 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.731); catalogued as rs527259841; called by muse, mutect2, varscan2
- PPP1R21 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV54289978; called by muse, mutect2, varscan2
- PPP3CA | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 91/147 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548076, COSV59921233; called by muse, mutect2, varscan2
- PRAMEF17 | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1166640954; called by muse, mutect2, varscan2
- PRDM10 | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 16/138 reads (12%) | catalogued as COSV58802665; called by muse, mutect2, varscan2
- PSG9 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 247/272 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs749016381; called by muse, mutect2, varscan2
- PSMD3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 150/289 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs555631976; called by muse, mutect2, varscan2
- PTPRD | c.3886G>T p.E1296* | Nonsense Mutation (SNP) | VAF 76/95 reads (80%) | catalogued as COSV61926583, COSV61978921; called by muse, mutect2, varscan2
- PXDNL | c.886A>T p.R296* | Nonsense Mutation (SNP) | VAF 106/488 reads (22%) | catalogued as COSV62487640; called by muse, mutect2, varscan2
- PYGM | c.2177G>A p.G726E | Missense Mutation (SNP) | VAF 47/387 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1190587944; called by muse, mutect2, varscan2
- QTRT2 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs764847068; called by muse, mutect2, varscan2
- RAB3IL1 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.505); catalogued as rs749370411; called by muse, mutect2, varscan2
- RASA2 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs770448162; called by muse, mutect2, varscan2
- RBMXL2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs755396057; called by muse, mutect2, varscan2
- RGS7 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 68/505 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.279); catalogued as rs372505807; called by muse, mutect2, varscan2
- RNF115 | c.704A>T p.Y235F | Missense Mutation (SNP) | VAF 137/345 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs782790501; called by muse, mutect2, varscan2
- RPTN | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 376/825 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60169158; called by muse, mutect2, varscan2
- RRM1 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.074); catalogued as rs779004662; called by muse, mutect2, varscan2
- RTN1 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 87/136 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV50718699, COSV50719661; called by muse, mutect2, varscan2
- RYR2 | c.9460G>T p.A3154S | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV63677166; called by muse, mutect2, varscan2
- RYR3 | c.4541G>T p.R1514L | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV66776059; called by muse, mutect2, varscan2
- SATB1 | c.759G>T p.M253I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1247937058; called by muse, mutect2, varscan2
- SCARA5 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 58/345 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs765093547; called by muse, mutect2, varscan2
- SCN5A | c.1726C>G p.P576A | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.055); catalogued as COSV61133873; called by muse, mutect2, varscan2
- SEMA3D | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99033659; called by muse, mutect2, varscan2
- SEMA4A | c.1587del p.N530Tfs*2 | Frame Shift Del (DEL) | VAF 26/136 reads (19%) | catalogued as rs1558163897; called by mutect2, pindel, varscan2
- SF3A1 | c.803G>C p.R268P | Missense Mutation (SNP) | VAF 90/441 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99305781; called by muse, mutect2, varscan2
- SKOR1 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs943427929, COSV58250085; called by muse, mutect2, varscan2
- SLC22A16 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1272718304; called by muse, mutect2, varscan2
- SLC3A1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.161); catalogued as rs753527558, COSV53224516; called by muse, mutect2, varscan2
- SLC4A3 | c.2731C>A p.R911S | Missense Mutation (SNP) | VAF 140/249 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56093013; called by muse, mutect2, varscan2
- SLC5A11 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 284/413 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs932697713, COSV61741032; called by muse, mutect2, varscan2
- SLC7A13 | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT tolerated (0.54); PolyPhen benign (0.045); catalogued as COSV52532273; called by muse, mutect2, varscan2
- SLIT1 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56595782; called by muse, mutect2, varscan2
- SNTG1 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 87/391 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99387058; called by muse, mutect2, varscan2
- SP3 | c.1334C>G p.P445R | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100022002; called by muse, mutect2, varscan2
- SPATA31A6 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 113/535 reads (21%) | catalogued as COSV60534229; called by muse, mutect2, varscan2
- SPTA1 | c.3189-1G>A p.X1063_splice | Splice Site (SNP) | VAF 90/376 reads (24%) | catalogued as COSV63760610; called by muse, mutect2, varscan2
- SRCAP | c.6724G>A p.E2242K | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52679522; called by muse, mutect2
- SRCAP | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as rs1386993634; called by muse, mutect2
- STAB1 | c.7091C>A p.T2364K | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100195323; called by muse, mutect2, varscan2
- STXBP5L | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 86/161 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV56510181, COSV56514530; called by muse, mutect2, varscan2
- SUGCT | c.1196G>T p.R399M (on ENST00000335693 / NM_001193313.2; = p.R425M on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 201/227 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100000648; called by muse, mutect2, varscan2
- SULF1 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 116/296 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201774043, COSV52690552; called by muse, mutect2, varscan2
- SVEP1 | c.1876del p.A626Qfs*25 | Frame Shift Del (DEL) | VAF 86/199 reads (43%) | catalogued as COSV57049750; called by mutect2, pindel, varscan2
- SYNE1 | c.16868G>A p.R5623H (on ENST00000367255 / NM_182961.4; = p.R5552H on NM_033071.3) | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs753544584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAP1 | c.2005A>G p.M669V | Missense Mutation (SNP) | VAF 98/639 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as rs765958228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBCK | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs35784409; called by muse, mutect2, varscan2
- TECPR2 | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV100850245; called by muse, mutect2
- TENT5D | c.275C>A p.P92Q | Missense Mutation (SNP) | VAF 94/196 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV57638237; called by muse, mutect2, varscan2
- TG | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 439/800 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.319); catalogued as COSV55071873; called by muse, mutect2, varscan2
- THBS2 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1477536579; called by muse, mutect2, varscan2
- TLL2 | c.2630A>G p.Q877R | Missense Mutation (SNP) | VAF 102/219 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1287812731; called by muse, mutect2, varscan2
- TMEFF2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV55840180; called by muse, mutect2, varscan2
- TMEM200A | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1331253259; called by muse, mutect2, varscan2
- TMEM260 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 41/485 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99839844; called by muse, mutect2
- TNN | c.412C>T p.L138= | Splice Region (SNP) | VAF 27/155 reads (17%) | catalogued as COSV53420870; called by muse, varscan2
- TPTE | c.1602G>T p.E534D (on ENST00000618007 / NM_199261.4; = p.E516D on NM_199259.4) | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as rs1319960887; called by muse, mutect2, varscan2
- TRAF1 | c.955A>G p.R319G | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1429770844; called by muse, mutect2, varscan2
- TRAJ53 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 39/160 reads (24%) | PolyPhen probably damaging (0.944); catalogued as rs900687390; called by muse, mutect2, varscan2
- TRAPPC9 | c.2580C>G p.F860L | Missense Mutation (SNP) | VAF 74/930 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.085); catalogued as COSV66896403; called by muse, mutect2
- TRIM10 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 142/300 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV100939565; called by muse, mutect2, varscan2
- TRIM58 | c.1384A>G p.T462A | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1201819173; called by muse, mutect2, varscan2
- TRIM7 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs954710762; called by muse, mutect2, varscan2
- TRPC5 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 134/236 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53285039; called by muse, mutect2, varscan2
- UBR2 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 108/221 reads (49%) | catalogued as COSV65749302; called by muse, mutect2, varscan2
- UNC13C | c.620G>T p.W207L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV52891998; called by muse, mutect2, varscan2
- UNC80 | c.7340G>A p.G2447E | Missense Mutation (SNP) | VAF 27/450 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV55887674; called by muse, mutect2
- USH2A | c.13561C>G p.P4521A | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV56406267; called by muse, mutect2, varscan2
- USH2A | c.9226G>T p.D3076Y | Missense Mutation (SNP) | VAF 101/417 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56401181, COSV56439100; called by muse, mutect2, varscan2
- USP6 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 330/428 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as rs750862063; called by muse, mutect2, varscan2
- VAT1L | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758626119, COSV56817365; called by muse, mutect2, varscan2
- VAV3 | c.1545C>A p.D515E | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58377874; called by muse, mutect2, varscan2
- VMP1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs368929171; called by muse, mutect2, varscan2
- VTCN1 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1490657225; called by muse, mutect2
- WDR90 | c.2941C>T p.P981S | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1327206833, COSV53469974; called by muse, mutect2, varscan2
- WDR97 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 52/576 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1250878822; called by muse, mutect2
- WSCD2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 103/259 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs753595241; called by mutect2, varscan2
- XIRP2 | c.7027C>T p.L2343F (on ENST00000628543; = p.L2518F on NM_152381.6) | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV54699812; called by muse, mutect2, varscan2
- XIRP2 | c.8725G>T p.V2909L (on ENST00000628543; = p.V3084L on NM_152381.6) | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV54728257, COSV99039766; called by muse, mutect2, varscan2
- ZEB2 | c.2156G>T p.S719I | Missense Mutation (SNP) | VAF 92/178 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100355670; called by muse, mutect2, varscan2
- ZFHX3 | c.6115C>T p.P2039S | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs760180670; called by muse, mutect2, varscan2
- ZFPM1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV60324082; called by muse, mutect2, varscan2
- ZNF232 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 49/483 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs745741402; called by muse, mutect2, varscan2
- ZNF423 | c.2211C>G p.F737L (on ENST00000563137 / NM_001379286.1; = p.F729L on NM_015069.4) | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99283511; called by muse, mutect2, varscan2
- ZNF438 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs199999473, COSV59194055; called by muse, mutect2, varscan2
- ZNF514 | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 116/138 reads (84%) | catalogued as COSV99727697; called by muse, mutect2, varscan2
- ZNF529 | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs765956981; called by muse, mutect2, varscan2
- ZNF606 | c.305-1G>A p.X102_splice | Splice Site (SNP) | VAF 28/103 reads (27%) | catalogued as COSV62047774; called by muse, mutect2, varscan2
- ZNF705A | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 110/279 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1424881100; called by muse, mutect2, varscan2
- ZNF717 | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs76889571, COSV68858133; called by muse, mutect2, varscan2
- ZP4 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs376995776; called by muse, mutect2, varscan2
- ZSCAN1 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 52/260 reads (20%) | catalogued as rs761346628, COSV56609383; called by muse, mutect2, varscan2
- ABCA8 | c.627G>T p.M209I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ABCC9 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC245033.1 | c.1677C>T p.D559= | Splice Region (SNP) | VAF 101/548 reads (18%) | called by muse, mutect2, varscan2
- ACIN1 | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ACOX1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 67/599 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM23 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 159/277 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS1 | c.1609G>T p.G537W | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADAMTS1 | c.1608A>C p.E536D | Missense Mutation (SNP) | VAF 68/95 reads (72%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS16 | c.745T>C p.C249R | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRA2 | c.3580G>T p.E1194* | Nonsense Mutation (SNP) | VAF 46/300 reads (15%) | called by muse, mutect2, varscan2
- ADGRA3 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ADGRE1 | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 79/89 reads (89%) | SIFT tolerated (0.09); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ALPK3 | c.4452C>G p.I1484M | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AMER1 | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- AMY2B | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 93/337 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANK1 | c.3575C>A p.T1192N | Missense Mutation (SNP) | VAF 296/448 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ANKRD34B | c.1349C>A p.P450Q | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APCS | c.467A>G p.Q156R | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APRT | c.251T>A p.V84E | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ARIH2 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 73/354 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ARMC4 | c.2007C>G p.I669M | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARMT1 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ART3 | c.198A>T p.L66F | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ART3 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ATP10B | c.2444T>A p.L815Q | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1547A>T p.Q516L | Missense Mutation (SNP) | VAF 216/513 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATP6V1G3 | c.27C>A p.H9Q | Missense Mutation (SNP) | VAF 187/356 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf88 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C12orf66 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 87/428 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- C17orf99 | c.369C>A p.S123= | Splice Region (SNP) | VAF 39/121 reads (32%) | called by muse, mutect2, varscan2
- C6orf118 | c.937-1G>C p.X313_splice | Splice Site (SNP) | VAF 24/48 reads (50%) | called by muse, varscan2
- CACNA1B | c.168G>T p.M56I | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CACNA1D | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CACNA1F | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 48/555 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- CADM2 | c.613G>C p.V205L (on ENST00000407528 / NM_001167674.2; = p.V207L on NM_153184.4) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CALD1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CASP12 | c.924+1G>T p.X308_splice | Splice Site (SNP) | VAF 8/65 reads (12%) | called by muse, varscan2
- CCDC168 | c.7754G>T p.G2585V | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CCDC170 | c.1935G>C p.K645N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CCDC171 | c.3031C>A p.L1011I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC89 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCL3 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.869); called by muse, varscan2
- CCNB3 | c.2209G>T p.A737S | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH23 | c.8641G>T p.V2881F | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CDH5 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CDHR1 | c.1117del p.Q373Rfs*42 | Frame Shift Del (DEL) | VAF 140/375 reads (37%) | called by mutect2, pindel, varscan2
- CENPJ | c.2769G>C p.E923D | Missense Mutation (SNP) | VAF 54/498 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CEP135 | c.3292dup p.R1098Kfs*6 | Frame Shift Ins (INS) | VAF 30/187 reads (16%) | called by mutect2, pindel, varscan2
- CFAP47 | c.2128T>A p.S710T | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CFAP47 | c.6914G>T p.R2305L | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP94 | c.1164G>T p.L388F (on ENST00000320267 / NM_001352064.2; = p.L394F on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/244 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- CHD6 | c.3322G>T p.G1108C | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD8 | c.1922C>T p.A641V (on ENST00000646647 / NM_001170629.2; = p.A362V on NM_020920.4) | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CHL1 | c.2569G>A p.D857N (on ENST00000397491 / NM_001253387.1; = p.D873N on NM_006614.4) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CHRD | c.1459G>T p.G487W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- CHST7 | c.1415G>T p.R472M | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLDN14 | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 110/224 reads (49%) | called by muse, mutect2, varscan2
- CLEC1A | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CLEC3A | c.488G>A p.W163* (on ENST00000651443; = p.W154* on NM_005752.6) | Nonsense Mutation (SNP) | VAF 115/384 reads (30%) | called by muse, mutect2, varscan2
- CLMN | c.648G>T p.R216S | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- CLSPN | c.1847G>T p.R616L | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNPY3 | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 46/151 reads (30%) | called by muse, varscan2
- COL4A2 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 108/185 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COP1 | c.652A>T p.R218W | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CORIN | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CPAMD8 | c.1037G>A p.C346Y (on ENST00000651564; = p.C299Y on NM_015692.5) | Missense Mutation (SNP) | VAF 97/135 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE8 | c.261dup p.E88* | Frame Shift Ins (INS) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- CRP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CSMD1 | c.9652C>A p.P3218T (on ENST00000520002; = p.P3217T on NM_033225.6) | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CSMD1 | c.5796C>A p.Y1932* (on ENST00000520002; = p.Y1931* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 110/213 reads (52%) | called by muse, mutect2, varscan2
- CTAGE9 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 158/439 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CYP2R1 | c.1012A>T p.K338* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | called by muse, mutect2, varscan2
- DACH1 | c.917del p.P306Rfs*12 | Frame Shift Del (DEL) | VAF 53/146 reads (36%) | called by mutect2, pindel, varscan2
- DERL1 | c.507G>T p.S169= | Splice Region (SNP) | VAF 14/213 reads (7%) | called by muse, mutect2
- DHDDS | c.951G>C p.L317F (on ENST00000236342 / NM_001319959.1; = p.L318F on NM_024887.3) | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DMD | c.9823G>C p.E3275Q | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.7992T>A p.H2664Q (on ENST00000409039; = p.H2603Q on NM_207437.3) | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH3 | c.5392G>A p.A1798T | Missense Mutation (SNP) | VAF 160/327 reads (49%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK10 | c.3126C>G p.Y1042* | Nonsense Mutation (SNP) | VAF 52/258 reads (20%) | called by muse, mutect2, varscan2
- DPEP1 | c.1000dup p.T334Nfs*11 | Frame Shift Ins (INS) | VAF 70/240 reads (29%) | called by mutect2, varscan2
- DPEP1 | c.1001delinsAA p.T334Kfs*11 | Frame Shift Ins (INS) | VAF 66/307 reads (21%) | called by mutect2*, pindel, varscan2*
- DROSHA | c.2578G>T p.A860S | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- DSG2 | c.1185T>G p.I395M | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- DST | c.6921A>T p.Q2307H | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2
- EDIL3 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- EIF2S2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2
- EIF4E2 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 151/385 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ELP1 | c.3798G>T p.M1266I | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESPN | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESX1 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- EYS | c.6328A>T p.N2110Y | Missense Mutation (SNP) | VAF 303/705 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FAM169A | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAM209B | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 359/832 reads (43%) | called by muse, mutect2, varscan2
- FAM47A | c.744_747del p.P249Gfs*16 | Frame Shift Del (DEL) | VAF 137/323 reads (42%) | called by mutect2, pindel, varscan2
- FAM9A | c.682del p.E228Rfs*71 | Frame Shift Del (DEL) | VAF 89/435 reads (20%) | called by mutect2, pindel, varscan2
- FAP | c.2250C>A p.H750Q | Missense Mutation (SNP) | VAF 118/261 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FASN | c.5992G>C p.G1998R | Missense Mutation (SNP) | VAF 386/745 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT1 | c.6135G>T p.E2045D | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAT2 | c.7383C>A p.F2461L | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAXC | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 98/179 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FER1L5 | c.2332_2334del p.V778del (on ENST00000623019; = p.V783del on NM_001293083.2) | In Frame Del (DEL) | VAF 29/169 reads (17%) | called by mutect2, pindel, varscan2
- FER1L6 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 103/722 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FER1L6 | c.5174C>A p.A1725D | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF13 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 336/373 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGG | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMN2 | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXC2 | c.1127C>G p.A376G | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FYB1 | c.89C>G p.S30* | Nonsense Mutation (SNP) | VAF 134/730 reads (18%) | called by muse, mutect2, varscan2
- GAK | c.569G>C p.C190S | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GATA4 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 82/373 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- GFRA4 | c.473C>T p.A158V (on ENST00000319242 / NM_145762.3; = p.P132S on NM_022139.4) | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- GK | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- GK3P | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 53/342 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GMPR | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 216/361 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GOLGA5 | c.841C>G p.R281G | Missense Mutation (SNP) | VAF 66/539 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA6L4 | c.639G>C p.E213D | Missense Mutation (SNP) | VAF 106/353 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GP2 | c.767T>C p.L256P (on ENST00000381362 / NM_001007240.3; = p.L253P on NM_001502.4) | Missense Mutation (SNP) | VAF 62/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR50 | c.1800C>A p.Y600* | Nonsense Mutation (SNP) | VAF 32/39 reads (82%) | called by muse, mutect2, varscan2
- GYS2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HAP1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HCK | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 112/281 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN1 | c.817A>T p.R273W | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HEATR5A | c.6032C>G p.A2011G | Missense Mutation (SNP) | VAF 47/692 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2
- HHIPL2 | c.2133G>T p.R711S | Missense Mutation (SNP) | VAF 170/297 reads (57%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIPK3 | c.2035A>T p.T679S | Missense Mutation (SNP) | VAF 77/88 reads (88%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HNF1B | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- HOXC13 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HRNR | c.1672T>A p.Y558N | Missense Mutation (SNP) | VAF 106/1031 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HSF2 | c.66C>A p.H22Q | Missense Mutation (SNP) | VAF 164/517 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ICAM3 | c.1206T>G p.I402M | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- IGF1R | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 174/438 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-16 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 73/322 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- IGKV1-17 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 270/448 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- IGLV3-19 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- IGSF3 | c.1629G>A p.M543I (on ENST00000369486 / NM_001007237.3; = p.M563I on NM_001542.4) | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INAVA | c.1546T>A p.Y516N | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- INPP4B | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- INSC | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 102/153 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- ITGB1 | c.1432C>A p.H478N | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ITSN2 | c.3178G>C p.V1060L | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- JMJD1C | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 139/273 reads (51%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KAT6B | c.1526A>T p.K509M | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KAT6B | c.4303G>T p.E1435* | Nonsense Mutation (SNP) | VAF 114/380 reads (30%) | called by muse, mutect2, varscan2
- KBTBD13 | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KCND1 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- KCND2 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 215/344 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KCNH7 | c.599T>C p.F200S | Missense Mutation (SNP) | VAF 132/404 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNJ15 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 101/265 reads (38%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNQ2 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 50/496 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL29 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LCE1A | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, varscan2
- LCOR | c.379A>T p.K127* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- LMLN | c.404del p.R135Hfs*111 | Frame Shift Del (DEL) | VAF 93/229 reads (41%) | called by mutect2, pindel, varscan2
- LPAR5 | c.974C>A p.T325K | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRBA | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC70 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 97/142 reads (68%) | SIFT tolerated (0.64); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LTBP2 | c.4228C>A p.R1410S | Missense Mutation (SNP) | VAF 309/597 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- MAFB | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 284/652 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB10 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.041); called by muse, mutect2
- MAGEB6B | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 212/427 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- MAGEB6B | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 89/361 reads (25%) | called by muse, mutect2, varscan2
- MALRD1 | c.3148T>G p.C1050G | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP3K19 | c.3706C>T p.P1236S | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K19 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP3K6 | c.2542C>T p.P848S | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP6 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- MARCO | c.1556G>T p.S519I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MARK1 | c.2246A>G p.Q749R | Missense Mutation (SNP) | VAF 41/363 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MARK1 | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCAT | c.512-2A>T p.X171_splice | Splice Site (SNP) | VAF 63/123 reads (51%) | called by muse, mutect2, varscan2
- MEF2C | c.237del p.T80Qfs*9 | Frame Shift Del (DEL) | VAF 66/145 reads (46%) | called by mutect2, pindel, varscan2
- MEIS1 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 299/371 reads (81%) | SIFT tolerated (0.76); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MINDY4B | c.824+1G>T p.X275_splice | Splice Site (SNP) | VAF 99/168 reads (59%) | called by muse, mutect2, varscan2
- MINK1 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- MORC1 | c.2284C>A p.L762I | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MRC2 | c.1569+1G>T p.X523_splice | Splice Site (SNP) | VAF 36/58 reads (62%) | called by muse, mutect2, varscan2
- MRM1 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSLNL | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MSMB | c.207T>A p.C69* | Nonsense Mutation (SNP) | VAF 104/245 reads (42%) | called by muse, mutect2, varscan2
- MTOR | c.4002G>T p.Q1334H | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MTUS2 | c.2308C>G p.L770V | Missense Mutation (SNP) | VAF 154/310 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC4 | c.6079A>G p.T2027A | Missense Mutation (SNP) | VAF 140/696 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.224); called by mutect2, varscan2
- MUC5B | c.6518G>A p.S2173N | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.878); called by mutect2, varscan2
- MUC5B | c.10289G>A p.S3430N | Missense Mutation (SNP) | VAF 41/626 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- MXRA5 | c.2559C>A p.H853Q | Missense Mutation (SNP) | VAF 97/356 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH2 | c.4187A>C p.K1396T | Missense Mutation (SNP) | VAF 101/876 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO7B | c.642del p.K215Sfs*12 | Frame Shift Del (DEL) | VAF 115/283 reads (41%) | called by mutect2, pindel, varscan2
- MYRF | c.1700C>T p.P567L (on ENST00000278836 / NM_001127392.3; = p.P558L on NM_013279.4) | Missense Mutation (SNP) | VAF 165/479 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- NEBL | c.446A>T p.K149I | Missense Mutation (SNP) | VAF 144/601 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- NLN | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NRAS | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- NRN1 | c.56C>A p.A19E | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- NUP153 | c.4367C>G p.S1456C | Missense Mutation (SNP) | VAF 27/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUP153 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP155 | c.723+2T>G p.X241_splice (on ENST00000231498 / NM_153485.3; = p.X182_splice on NM_004298.4) | Splice Site (SNP) | VAF 53/491 reads (11%) | called by muse, mutect2, varscan2
- NVL | c.2375A>G p.D792G | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NXPE3 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OGDHL | c.1422C>G p.C474W | Missense Mutation (SNP) | VAF 134/262 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR13F1 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 122/198 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- OR2AT4 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2
- OR3A2 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 123/232 reads (53%) | called by muse, mutect2, varscan2
- OR4C11 | c.748G>C p.G250R | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR4K1 | c.896G>T p.W299L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5L2 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 178/206 reads (86%) | called by muse, mutect2, varscan2
- OR6B2 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- OR6K6 | c.140A>T p.H47L (on ENST00000368144; = p.H23L on NM_001005184.1) | Missense Mutation (SNP) | VAF 199/500 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTOGL | c.6337G>T p.D2113Y (on ENST00000547103; = p.D2104Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- OTUD7A | c.1365G>C p.E455D (on ENST00000307050 / NM_001382637.1; = p.E448D on NM_130901.3) | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- P2RX3 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.54); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC5 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PALLD | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 194/637 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PARD3 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCDHA12 | c.2308A>T p.M770L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PCDHGA9 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PCDHGB6 | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PDE7B | c.492_494del p.E164del | In Frame Del (DEL) | VAF 20/134 reads (15%) | called by pindel, varscan2
- PDE9A | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PGAP6 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHKA2 | c.1270del p.D424Ifs*3 | Frame Shift Del (DEL) | VAF 104/531 reads (20%) | called by mutect2, pindel, varscan2
- PIGA | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PKD1 | c.7042A>G p.K2348E | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PKD1 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLA2G7 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 40/544 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLBD2 | c.860-1G>T p.X287_splice | Splice Site (SNP) | VAF 94/207 reads (45%) | called by muse, mutect2, varscan2
- PLBD2 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PLCB1 | c.3440A>T p.E1147V | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- PLCXD2 | c.567C>A p.C189* | Nonsense Mutation (SNP) | VAF 44/288 reads (15%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.2261G>T p.G754V (on ENST00000283426; = p.G1110V on NM_052909.5) | Missense Mutation (SNP) | VAF 255/734 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLEKHG4B | c.2909C>T p.A970V (on ENST00000283426; = p.A1326V on NM_052909.5) | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLG | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLOD3 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 381/638 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLRG1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- POF1B | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- POM121L12 | c.45dup p.W16Lfs*130 | Frame Shift Ins (INS) | VAF 32/84 reads (38%) | called by mutect2, pindel
- POTEA | c.917A>G p.K306R (on ENST00000519951 / NM_001005365.2; = p.K260R on NM_001002920.1) | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- POU3F3 | c.879C>A p.H293Q | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by mutect2, varscan2
- POU5F1B | c.272A>T p.E91V | Missense Mutation (SNP) | VAF 52/614 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- PPM1G | c.870G>C p.E290D | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PRAMEF20 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 39/395 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2
- PRB1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- PRKAA2 | c.1478C>G p.A493G | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKCB | c.169A>T p.I57F | Missense Mutation (SNP) | VAF 99/367 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PRKDC | c.9164G>T p.G3055V | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTCH2 | c.3134G>A p.G1045D | Missense Mutation (SNP) | VAF 166/420 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTK2B | c.1917G>C p.E639D | Missense Mutation (SNP) | VAF 76/463 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PTTG1 | c.520T>A p.W174R | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- QKI | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- QRICH1 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RAD51AP2 | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- RAP1GDS1 | c.73G>T p.G25* (on ENST00000408927 / NM_001100427.2; = p.G26* on NM_021159.5) | Nonsense Mutation (SNP) | VAF 36/220 reads (16%) | called by muse, mutect2, varscan2
- RASGRP4 | c.1708C>A p.R570S | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RASIP1 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM15 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RBM15 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.218); called by mutect2, varscan2
- RBM15B | c.832del p.R278Vfs*50 | Frame Shift Del (DEL) | VAF 73/226 reads (32%) | called by mutect2, pindel, varscan2
- RBMXL3 | c.1741C>A p.Q581K | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX7 | c.635G>C p.R212P (on ENST00000559447 / NM_001368074.1; = p.R309P on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/333 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RGS5 | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RNF13 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- RNF148 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS6KA6 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- RSRC2 | c.184A>G p.R62G | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RYR3 | c.6381C>A p.A2127= | Splice Region (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- SALL3 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- SALL4 | c.1581C>G p.N527K | Missense Mutation (SNP) | VAF 36/573 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- SAP130 | c.2988+1G>T p.X996_splice | Splice Site (SNP) | VAF 80/144 reads (56%) | called by muse, mutect2, varscan2
- SAXO1 | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 183/212 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SAXO1 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCAF11 | c.3778G>T p.G1260* | Nonsense Mutation (SNP) | VAF 28/356 reads (8%) | called by muse, mutect2
- SCG2 | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 148/433 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SCN3A | c.4807+5G>C | Splice Region (SNP) | VAF 38/310 reads (12%) | called by muse, mutect2, varscan2
- SCRT1 | c.32A>G p.K11R | Missense Mutation (SNP) | VAF 194/360 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SEL1L3 | c.2670-1G>T p.X890_splice | Splice Site (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2, varscan2
- SEMA3B | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SETD4 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 102/427 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SETX | c.7367G>C p.R2456T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SIPA1L2 | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 90/293 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SLC2A12 | c.785A>G p.Q262R | Missense Mutation (SNP) | VAF 86/155 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLC2A13 | c.1557_1559del p.F520del | In Frame Del (DEL) | VAF 58/212 reads (27%) | called by pindel, varscan2
- SLC8A1 | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 58/80 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO5A1 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLITRK1 | c.1556C>A p.T519N | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMG5 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2
- SMYD5 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 200/228 reads (88%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOD3 | c.417C>A p.H139Q | Missense Mutation (SNP) | VAF 411/628 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31E1 | c.1002C>A p.H334Q | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SRGAP1 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 147/199 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- STAB1 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- STYXL2 | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SUCNR1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUGP1 | c.194del p.P65Hfs*30 | Frame Shift Del (DEL) | VAF 138/200 reads (69%) | called by mutect2, pindel, varscan2
- SVEP1 | c.5924C>G p.T1975R | Missense Mutation (SNP) | VAF 91/146 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- SYNE2 | c.2623G>T p.G875C | Missense Mutation (SNP) | VAF 232/403 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- TAF15 | c.376C>T p.Q126* (on ENST00000605844 / NM_139215.3; = p.Q123* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 43/284 reads (15%) | called by muse, mutect2, varscan2
- TBC1D24 | c.1374G>T p.L458F (on ENST00000646147 / NM_001199107.2; = p.L452F on NM_020705.3) | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- TCP10L | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TDRD15 | c.4418C>A p.S1473* | Nonsense Mutation (SNP) | VAF 36/174 reads (21%) | called by muse, mutect2, varscan2
- TESPA1 | c.190T>C p.W64R | Missense Mutation (SNP) | VAF 255/359 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX13B | c.78del p.R27Gfs*85 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- TFAP4 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 100/443 reads (23%) | called by muse, mutect2, varscan2
- TFDP3 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- THBS3 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THSD7B | c.4192G>T p.G1398C (on ENST00000272643; = p.G1396C on NM_001316349.2) | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIGD2 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TLR6 | c.1665G>T p.W555C | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLR8 | c.1473C>G p.N491K (on ENST00000218032 / NM_138636.5; = p.N509K on NM_016610.4) | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM121 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TMEM200A | c.1440C>G p.N480K | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TMEM237 | c.1172C>A p.S391Y (on ENST00000409883 / NM_001044385.3; = p.S383Y on NM_152388.4) | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TMEM263 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TMEM40 | c.418_424+17del p.X140_splice | Splice Site (DEL) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- TOP2B | c.4468A>G p.K1490E (on ENST00000264331 / NM_001330700.2; = p.K1485E on NM_001068.3) | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TRHDE | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 71/457 reads (16%) | called by muse, mutect2, varscan2
- TRIM58 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TRIM69 | c.1460G>T p.G487V (on ENST00000329464 / NM_182985.5; = p.G328V on NM_080745.5) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, varscan2
- TRPC4 | c.2700_2701insA p.G901Rfs*4 (on ENST00000379705 / NM_016179.4; = p.G906Rfs*4 on NM_003306.3) | Frame Shift Ins (INS) | VAF 26/95 reads (27%) | called by mutect2, pindel, varscan2
- TRPM6 | c.1661A>T p.N554I | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- TRPS1 | c.1127A>T p.E376V (on ENST00000220888 / NM_001330599.2; = p.E389V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/634 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- TRPS1 | c.1126G>T p.E376* (on ENST00000220888 / NM_001330599.2; = p.E389* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 100/638 reads (16%) | called by muse, mutect2, varscan2
- TSC2 | c.2286G>T p.L762F | Missense Mutation (SNP) | VAF 169/336 reads (50%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPYL2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 104/456 reads (23%) | called by muse, mutect2, varscan2
- TTC6 | c.2917G>T p.D973Y | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTLL13P | c.2318C>G p.S773* | Nonsense Mutation (SNP) | VAF 73/351 reads (21%) | called by muse, mutect2, varscan2
- UBR3 | c.5576A>T p.K1859M | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- UNC13C | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- UNC45B | c.2605C>A p.L869M | Missense Mutation (SNP) | VAF 129/481 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC5D | c.2474T>C p.L825P | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- UNC79 | c.4549C>A p.H1517N (on ENST00000393151 / NM_001346218.2; = p.H1340N on NM_020818.5) | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- UNC80 | c.8716A>T p.K2906* | Nonsense Mutation (SNP) | VAF 44/162 reads (27%) | called by muse, mutect2, varscan2
- USP48 | c.1451-3C>G | Splice Region (SNP) | VAF 47/177 reads (27%) | called by muse, mutect2, varscan2
- UTP18 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 124/190 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VPS13B | c.3984G>C p.W1328C | Missense Mutation (SNP) | VAF 80/415 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- VPS45 | c.522G>C p.M174I | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- VWA5B1 | c.2223C>G p.C741W | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- WASHC3 | c.480del p.L161* | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
- WDFY4 | c.4052C>A p.A1351D | Missense Mutation (SNP) | VAF 150/278 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- WDR43 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WEE2 | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- XAGE5 | c.115del p.E39Kfs*89 | Frame Shift Del (DEL) | VAF 87/205 reads (42%) | called by mutect2, pindel, varscan2
- XIRP1 | c.4898C>T p.A1633V | Missense Mutation (SNP) | VAF 17/335 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- XIRP2 | c.2256T>A p.D752E (on ENST00000628543; = p.D927E on NM_152381.6) | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- XKR6 | c.1846G>A p.V616I | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- YIPF6 | c.594C>A p.A198= | Splice Region (SNP) | VAF 64/161 reads (40%) | called by muse, mutect2, varscan2
- ZAN | c.6200G>T p.G2067V | Missense Mutation (SNP) | VAF 91/160 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB2 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 157/335 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ZBTB21 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 62/142 reads (44%) | called by muse, mutect2, varscan2
- ZC3H15 | c.93G>C p.L31F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFP82 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 105/113 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ZIC5 | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 178/351 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF136 | c.1100A>T p.K367M | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF257 | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 134/152 reads (88%) | called by muse, mutect2, varscan2
- ZNF441 | c.1510A>T p.K504* | Nonsense Mutation (SNP) | VAF 112/137 reads (82%) | called by muse, mutect2, varscan2
- ZNF469 | c.11707C>A p.L3903I (on ENST00000437464; = p.L3931I on NM_001367624.2) | Missense Mutation (SNP) | VAF 27/598 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- ZNF521 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ZNF600 | c.503del p.G168Afs*10 | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | called by mutect2, pindel, varscan2
- ZNF615 | c.1725A>T p.K575N | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF623 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 26/546 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2
- ZNF626 | c.102A>T p.L34F | Missense Mutation (SNP) | VAF 298/332 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, varscan2
- ZNF638 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 49/189 reads (26%) | PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ZNF679 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZNF804A | c.3503A>T p.Q1168L | Missense Mutation (SNP) | VAF 107/324 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZNF831 | c.1333C>A p.P445T | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- ZNF831 | c.4529G>T p.S1510I | Missense Mutation (SNP) | VAF 179/390 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF853 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 173/192 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZSCAN18 | c.1504C>G p.P502A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACMSD | c.510C>T p.S170= | Silent (SNP) | VAF 48/392 reads (12%) | called by muse, varscan2
- ACSM2A | c.1212C>A p.P404= (on ENST00000219054; = p.P325= on NM_001308169.2) | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as COSV54584720; called by muse, mutect2, varscan2
- ADAM23 | c.2337C>A p.P779= | Silent (SNP) | VAF 114/608 reads (19%) | catalogued as rs571615571, COSV52217714; called by muse, varscan2
- ADGRA2 | c.3579G>T p.G1193= | Silent (SNP) | VAF 47/311 reads (15%) | called by muse, mutect2, varscan2
- AMER3 | c.1548C>A p.P516= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs1319690380; called by muse, mutect2, varscan2
- ARAP3 | c.213G>T p.L71= | Silent (SNP) | VAF 60/117 reads (51%) | called by muse, mutect2, varscan2
- ARNT | c.1755C>A p.S585= | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- ASB16 | c.1356C>A p.I452= | Silent (SNP) | VAF 104/182 reads (57%) | called by muse, varscan2
- ATAD3B | c.429C>T p.A143= (on ENST00000308647; = p.A249= on NM_031921.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/57 reads (68%) | called by muse, mutect2, varscan2
- AXDND1 | c.825G>T p.V275= | Silent (SNP) | VAF 218/380 reads (57%) | called by muse, mutect2, varscan2
- BRINP1 | c.1878T>A p.P626= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV99776462, COSV99777042; called by muse, mutect2, varscan2
- BTF3 | c.612G>A p.E204= (on ENST00000380591 / NM_001037637.1; = p.E160= on NM_001207.4) | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs961437822; called by muse, mutect2, varscan2
- BUB3 | c.114C>G p.S38= | Silent (SNP) | VAF 38/200 reads (19%) | called by muse, mutect2, varscan2
- C11orf49 | c.105G>A p.R35= | Silent (SNP) | VAF 42/232 reads (18%) | called by muse, mutect2, varscan2
- C1QL2 | c.447G>A p.A149= | Silent (SNP) | VAF 110/292 reads (38%) | called by muse, mutect2, varscan2
- CABS1 | c.853C>T p.L285= | Silent (SNP) | VAF 46/218 reads (21%) | catalogued as rs201758701; called by muse, mutect2, varscan2
- CBLN4 | c.453G>T p.A151= | Silent (SNP) | VAF 78/784 reads (10%) | called by muse, mutect2
- CCDC168 | c.14673G>A p.R4891= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- CD84 | c.996C>T p.D332= (on ENST00000311224 / NM_001184879.2; = p.D315= on NM_003874.4) | Silent (SNP) | VAF 183/388 reads (47%) | called by muse, mutect2, varscan2
- CD93 | c.634T>C p.L212= | Silent (SNP) | VAF 34/224 reads (15%) | called by muse, varscan2
- CD93 | c.633C>A p.S211= | Silent (SNP) | VAF 37/228 reads (16%) | catalogued as COSV55665043; called by muse, mutect2, varscan2
- CEP131 | c.1734G>T p.L578= (on ENST00000269392 / NM_001319228.2; = p.L575= on NM_014984.4) | Silent (SNP) | VAF 81/325 reads (25%) | called by muse, mutect2, varscan2
- CEP135 | c.861G>T p.L287= | Silent (SNP) | VAF 72/132 reads (55%) | called by muse, mutect2, varscan2
- CFAP46 | c.1251G>A p.L417= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as rs915842697; called by muse, mutect2, varscan2
- CFAP52 | c.1395C>A p.S465= | Silent (SNP) | VAF 41/512 reads (8%) | called by muse, mutect2
- CFAP97 | c.1206G>A p.A402= | Silent (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- CHAT | c.1116C>T p.S372= | Silent (SNP) | VAF 92/687 reads (13%) | called by muse, mutect2, varscan2
- CHRND | c.18G>C p.L6= | Silent (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2, varscan2
- CLDN2 | c.141C>T p.S47= | Silent (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- CLEC4M | c.945A>T p.L315= | Silent (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- COL11A1 | c.5119C>A p.R1707= | Silent (SNP) | VAF 128/330 reads (39%) | catalogued as rs757608461, COSV62179966, COSV62203151; called by muse, mutect2, varscan2
- COL12A1 | c.7311C>G p.S2437= | Silent (SNP) | VAF 35/299 reads (12%) | catalogued as COSV59400696; called by muse, mutect2, varscan2
- COL24A1 | c.2826T>A p.G942= | Silent (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- COL9A2 | c.498G>T p.L166= | Silent (SNP) | VAF 126/250 reads (50%) | called by muse, varscan2
- CPOX | c.390C>T p.F130= | Silent (SNP) | VAF 200/654 reads (31%) | called by muse, mutect2, varscan2
- CRB2 | c.2115C>A p.I705= | Silent (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- CSMD3 | c.9822A>T p.V3274= (on ENST00000297405 / NM_001363185.1; = p.V3105= on NM_052900.3) | Silent (SNP) | VAF 141/830 reads (17%) | catalogued as COSV52209229; called by muse, mutect2, varscan2
- CT47B1 | c.219C>G p.A73= | Silent (SNP) | VAF 349/442 reads (79%) | catalogued as COSV64891143; called by muse, mutect2, varscan2
- CTF1 | c.600G>A p.S200= | Silent (SNP) | VAF 53/204 reads (26%) | catalogued as rs1026759136; called by muse, mutect2, varscan2
- CUX2 | c.2187G>A p.E729= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- CYP2C19 | c.273A>T p.G91= | Silent (SNP) | VAF 49/258 reads (19%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.306C>A p.I102= | Silent (SNP) | VAF 97/423 reads (23%) | called by muse, mutect2, varscan2
- DDX39A | c.840C>G p.L280= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV54391403; called by muse, mutect2, varscan2
- DIAPH1 | c.2205C>T p.G735= | Silent (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- DLGAP4 | c.795T>A p.T265= | Silent (SNP) | VAF 73/647 reads (11%) | called by muse, mutect2, varscan2
- DNAI2 | c.912G>T p.V304= | Silent (SNP) | VAF 301/435 reads (69%) | called by muse, mutect2, varscan2
- DOK6 | c.774C>A p.S258= | Silent (SNP) | VAF 109/137 reads (80%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.10086C>T p.Y3362= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV62093597; called by muse, varscan2
- DYTN | c.1485T>A p.V495= | Silent (SNP) | VAF 126/915 reads (14%) | called by muse, mutect2, varscan2
- ECE1 | c.207G>T p.L69= | Silent (SNP) | VAF 81/308 reads (26%) | called by muse, mutect2, varscan2
- EPHA1 | c.1737G>A p.Q579= | Silent (SNP) | VAF 26/202 reads (13%) | called by muse, varscan2
- ERBB4 | c.318T>A p.R106= | Silent (SNP) | VAF 135/779 reads (17%) | called by muse, mutect2, varscan2
- EVPL | c.1914G>A p.E638= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- FAM120C | c.2929C>A p.R977= | Silent (SNP) | VAF 149/291 reads (51%) | called by muse, mutect2, varscan2
- FBN1 | c.5004C>T p.G1668= | Silent (SNP) | VAF 62/330 reads (19%) | called by muse, mutect2, varscan2
- FBXO28 | c.993T>A p.A331= | Silent (SNP) | VAF 50/335 reads (15%) | called by muse, mutect2, varscan2
- FCGBP | c.600G>T p.V200= | Silent (SNP) | VAF 224/250 reads (90%) | called by muse, mutect2, varscan2
- FCRL3 | c.1428C>T p.P476= | Silent (SNP) | VAF 156/273 reads (57%) | catalogued as rs1468155648, COSV100943017, COSV63840188; called by muse, mutect2, varscan2
- FECH | c.456C>T p.P152= | Silent (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- FHL1 | c.420C>T p.S140= | Silent (SNP) | VAF 207/625 reads (33%) | called by muse, mutect2, varscan2
- FLG | c.8379C>T p.S2793= | Silent (SNP) | VAF 482/2763 reads (17%) | catalogued as rs747057114, COSV64240050, COSV64240779; called by muse, mutect2, varscan2
- FLNC | c.7761C>A p.P2587= | Silent (SNP) | VAF 177/304 reads (58%) | called by muse, mutect2, varscan2
- FN3K | c.324A>C p.A108= | Silent (SNP) | VAF 90/969 reads (9%) | called by muse, mutect2
- GALK1 | c.498C>T p.R166= | Silent (SNP) | VAF 60/191 reads (31%) | catalogued as rs763880577; called by muse, mutect2, varscan2
- GAS2L2 | c.417G>T p.V139= | Silent (SNP) | VAF 165/272 reads (61%) | catalogued as rs781922164; called by muse, mutect2, varscan2
- GAS8 | c.60G>T p.G20= | Silent (SNP) | VAF 100/247 reads (40%) | called by muse, mutect2, varscan2
- GIGYF2 | c.1269C>T p.P423= | Silent (SNP) | VAF 56/517 reads (11%) | catalogued as COSV101004208; called by muse, mutect2, varscan2
- GIPR | c.741C>T p.L247= | Silent (SNP) | VAF 94/1816 reads (5%) | catalogued as COSV99624748; called by muse, mutect2
- GMPPB | c.1008C>A p.L336= (on ENST00000308388 / NM_021971.4; = p.L363= on NM_013334.3) | Silent (SNP) | VAF 58/99 reads (59%) | called by muse, mutect2, varscan2
- GNAT1 | c.27G>A p.E9= | Silent (SNP) | VAF 50/218 reads (23%) | catalogued as COSV104372303; called by muse, mutect2, varscan2
- GPR45 | c.621C>T p.P207= | Silent (SNP) | VAF 62/294 reads (21%) | catalogued as rs778070417; called by muse, mutect2, varscan2
- GRIP1 | c.3114G>A p.G1038= (on ENST00000359742 / NM_001379345.1; = p.G986= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 471/600 reads (79%) | called by muse, mutect2, varscan2
- GRM6 | c.24G>A p.R8= | Silent (SNP) | VAF 30/41 reads (73%) | called by muse, mutect2, varscan2
- GSC | c.186G>A p.V62= | Silent (SNP) | VAF 182/302 reads (60%) | called by muse, mutect2, varscan2
- HELZ2 | c.3861G>C p.L1287= (on ENST00000467148 / NM_001037335.2; = p.L718= on NM_033405.3) | Silent (SNP) | VAF 39/181 reads (22%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.528T>G p.T176= (on ENST00000394468 / NM_001039372.4; = p.T164= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 291/496 reads (59%) | called by muse, mutect2, varscan2
- HMCN1 | c.11865T>A p.L3955= | Silent (SNP) | VAF 205/487 reads (42%) | called by muse, mutect2, varscan2
- HOXD8 | c.273G>A p.Q91= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1384947761; called by muse, mutect2, varscan2
- HPS5 | c.690G>T p.G230= (on ENST00000349215 / NM_181507.2; = p.G116= on NM_007216.4) | Silent (SNP) | VAF 219/249 reads (88%) | catalogued as COSV62540412; called by muse, mutect2, varscan2
- HSD17B14 | c.438C>T p.I146= | Silent (SNP) | VAF 46/283 reads (16%) | catalogued as rs769505004; called by muse, mutect2, varscan2
- IGF2BP1 | c.105C>G p.V35= | Silent (SNP) | VAF 21/315 reads (7%) | called by muse, mutect2
- IGKV3-15 | c.204C>A p.I68= | Silent (SNP) | VAF 273/1041 reads (26%) | catalogued as rs755211568; called by muse, mutect2, varscan2
- IL6R | c.546G>A p.E182= | Silent (SNP) | VAF 48/569 reads (8%) | catalogued as COSV100691209; called by muse, mutect2
- INSC | c.762C>A p.T254= | Silent (SNP) | VAF 100/150 reads (67%) | catalogued as COSV65412910; called by muse, mutect2
- IPP | c.903G>A p.G301= | Silent (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- IQSEC2 | c.756A>T p.P252= (on ENST00000642864 / NM_001111125.3; = p.P47= on NM_015075.2) | Silent (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2
- IRX1 | c.1392G>A p.L464= | Silent (SNP) | VAF 55/736 reads (7%) | called by muse, mutect2
- ITPKB | c.2796C>G p.L932= | Silent (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- JAK3 | c.1020G>T p.S340= | Silent (SNP) | VAF 52/705 reads (7%) | catalogued as COSV71686482; called by muse, mutect2
- KDM4D | c.516A>T p.I172= | Silent (SNP) | VAF 273/306 reads (89%) | called by muse, mutect2, varscan2
- KIAA1217 | c.399G>T p.L133= | Silent (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- KIF16B | c.489G>T p.R163= | Silent (SNP) | VAF 54/88 reads (61%) | called by muse, mutect2, varscan2
- KRT4 | c.582C>G p.V194= | Silent (SNP) | VAF 113/1295 reads (9%) | called by muse, mutect2
- LBP | c.954C>G p.T318= | Silent (SNP) | VAF 167/425 reads (39%) | called by muse, mutect2, varscan2
- LEUTX | c.258T>G p.R86= | Silent (SNP) | VAF 346/384 reads (90%) | called by muse, mutect2, varscan2
- LRRC6 | c.699G>A p.E233= | Silent (SNP) | VAF 22/285 reads (8%) | catalogued as COSV51542492; called by muse, mutect2
- LRRIQ3 | c.1431G>A p.E477= | Silent (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- LRRN4 | c.1782G>T p.T594= | Silent (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- MACF1 | c.20775G>A p.E6925= (on ENST00000372915; = p.E4970= on NM_012090.5) | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- MADCAM1 | c.996G>T p.L332= | Silent (SNP) | VAF 117/168 reads (70%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1845C>A p.A615= | Silent (SNP) | VAF 150/168 reads (89%) | catalogued as COSV100026254; called by muse, mutect2, varscan2
- MALRD1 | c.3582C>T p.L1194= | Silent (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- MAP3K15 | c.2553C>T p.F851= | Silent (SNP) | VAF 34/291 reads (12%) | called by muse, varscan2
- MAST3 | c.3024G>A p.G1008= | Silent (SNP) | VAF 43/344 reads (13%) | called by muse, mutect2, varscan2
- MCL1 | c.582G>A p.K194= | Silent (SNP) | VAF 39/551 reads (7%) | called by muse, mutect2
- MDN1 | c.6210G>T p.V2070= | Silent (SNP) | VAF 187/686 reads (27%) | called by muse, mutect2, varscan2
- MEAK7 | c.804G>T p.L268= | Silent (SNP) | VAF 145/306 reads (47%) | catalogued as COSV59145253; called by muse, mutect2, varscan2
- MEGF11 | c.285C>T p.S95= | Silent (SNP) | VAF 89/206 reads (43%) | catalogued as rs878944232, COSV99987805; called by muse, mutect2, varscan2
- MKRN3 | c.1275C>A p.G425= | Silent (SNP) | VAF 110/263 reads (42%) | called by muse, mutect2, varscan2
- MRPS21 | c.165A>G p.E55= | Silent (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- MRTFA | c.1080C>T p.A360= | Silent (SNP) | VAF 84/230 reads (37%) | catalogued as rs1392573674, COSV62933382; called by muse, mutect2, varscan2
- MSR1 | c.636C>A p.I212= | Silent (SNP) | VAF 73/191 reads (38%) | called by muse, mutect2, varscan2
- MUC16 | c.6579C>A p.S2193= | Silent (SNP) | VAF 53/65 reads (82%) | called by muse, mutect2, varscan2
- MUC22 | c.300C>T p.D100= | Silent (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- MUCL3 | c.900C>A p.S300= | Silent (SNP) | VAF 265/575 reads (46%) | called by muse, mutect2, varscan2
- MYH13 | c.4104C>T p.A1368= | Silent (SNP) | VAF 83/770 reads (11%) | catalogued as rs377365193; called by muse, mutect2, varscan2
- MYO18B | c.6810G>T p.L2270= | Silent (SNP) | VAF 66/145 reads (46%) | called by muse, mutect2, varscan2
- MYOM2 | c.1086C>A p.G362= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as COSV50718277; called by muse, mutect2, varscan2
- NBEA | c.4857T>C p.H1619= | Silent (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- NMBR | c.1060C>T p.L354= | Silent (SNP) | VAF 81/209 reads (39%) | called by muse, mutect2, varscan2
- NTF4 | c.366C>A p.G122= | Silent (SNP) | VAF 145/355 reads (41%) | called by muse, mutect2, varscan2
- NUTM1 | c.1308G>T p.L436= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as rs749670673; called by muse, mutect2, varscan2
- OAS2 | c.1902G>T p.V634= | Silent (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- OR10G3 | c.837C>T p.A279= | Silent (SNP) | VAF 61/110 reads (55%) | called by muse, mutect2, varscan2
- OR10K1 | c.904C>A p.R302= | Silent (SNP) | VAF 95/206 reads (46%) | catalogued as COSV56870768, COSV99193382; called by muse, mutect2, varscan2
- OR10K2 | c.207T>A p.S69= | Silent (SNP) | VAF 227/475 reads (48%) | called by muse, mutect2, varscan2
- OR10X1 | c.180C>T p.I60= | Silent (SNP) | VAF 88/348 reads (25%) | catalogued as COSV100936618; called by muse, mutect2, varscan2
- OR1J4 | c.930C>A p.V310= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- OR2T27 | c.213C>A p.I71= | Silent (SNP) | VAF 45/249 reads (18%) | called by muse, mutect2, varscan2
- OR4P4 | c.369C>T p.A123= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs1274808152; called by muse, mutect2, varscan2
- OR7E24 | c.927C>T p.S309= | Silent (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- OR9G4 | c.861T>C p.P287= | Silent (SNP) | VAF 63/246 reads (26%) | called by muse, mutect2, varscan2
- P4HA3 | c.393G>A p.E131= | Silent (SNP) | VAF 39/319 reads (12%) | called by muse, mutect2, varscan2
- PARK7 | c.303G>A p.L101= | Silent (SNP) | VAF 86/381 reads (23%) | called by muse, mutect2, varscan2
- PCDH10 | c.1800C>T p.L600= | Silent (SNP) | VAF 77/208 reads (37%) | catalogued as COSV99993195; called by muse, mutect2, varscan2
- PCDHA9 | c.474C>G p.S158= | Silent (SNP) | VAF 195/378 reads (52%) | catalogued as rs781916641, COSV65325536; called by muse, mutect2, varscan2
- PDYN | c.366G>A p.L122= | Silent (SNP) | VAF 105/579 reads (18%) | called by muse, mutect2, varscan2
- PDZD2 | c.7455G>C p.L2485= | Silent (SNP) | VAF 32/402 reads (8%) | catalogued as COSV56854914; called by muse, mutect2
- PGM5 | c.1518C>A p.I506= | Silent (SNP) | VAF 96/138 reads (70%) | called by muse, mutect2, varscan2
- PIGG | c.2799G>T p.T933= (on ENST00000453061 / NM_001127178.3; = p.T925= on NM_017733.4) | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV99573659; called by muse, mutect2, varscan2
- PLA2G7 | c.393T>C p.P131= | Silent (SNP) | VAF 42/550 reads (8%) | catalogued as rs201390481; called by muse, mutect2
- POU5F2 | c.81G>A p.L27= | Silent (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- PREX1 | c.3456C>A p.A1152= | Silent (SNP) | VAF 275/583 reads (47%) | called by muse, mutect2, varscan2
- PROKR2 | c.915C>T p.F305= | Silent (SNP) | VAF 67/455 reads (15%) | catalogued as rs1351399715, COSV54085406; called by muse, mutect2, varscan2
- PRR23B | c.738G>T p.A246= | Silent (SNP) | VAF 52/85 reads (61%) | catalogued as COSV61493405; called by muse, mutect2, varscan2
- PTCH2 | c.3135C>A p.G1045= | Silent (SNP) | VAF 165/416 reads (40%) | called by muse, mutect2, varscan2
- PTGIS | c.810G>A p.E270= | Silent (SNP) | VAF 93/893 reads (10%) | catalogued as rs1355808921; called by muse, mutect2, varscan2
- RANBP3 | c.618A>T p.A206= | Silent (SNP) | VAF 65/86 reads (76%) | called by muse, mutect2, varscan2
- RBFOX1 | c.159A>T p.T53= | Silent (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
159 further variants in this file (0 protein-altering or splice-affecting, 54 silent, 105 other) are not listed here.
